CPTAC case C3L-02890 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6f0fb9d7-64b5-4737-913c-1ac7d2a116a9

Demographics
Sex at birth: male; Year of birth: 1951; Vital status: Dead; Days to death: 1,007 days (2.8 years); Year of death: 2020; Cause of death: Cancer Related; Country of birth: Canada.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 65.8 years (24,050 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,007 days (2.8 years); Progression or recurrence: yes; Days to recurrence: 868 days (2.4 years); Days to last follow up: 1,007 days (2.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 7.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 6; Lymph nodes tested: 10; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 491 days (1.3 years); Disease response: Complete Response; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 785 days (2.1 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,007 days (2.8 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 868 days (2.4 years); Karnofsky performance status: 50; ECOG performance status: 2.

Other clinical attributes
- Weight: 64 kg; Height: 170 cm; BMI: 22.15; Diabetes treatment type: Insulin.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Alcohol history: Yes; Alcohol intensity: Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02890-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -15 days; Initial weight: 73.7 mg; Time between excision and freezing: 42 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02890-21: Section location: Head; Percent tumor nuclei: 10; Percent necrosis: 0.
- Sample C3L-02890-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -15 days; Initial weight: 84.1 mg; Time between excision and freezing: 42 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02890-22: Section location: Head; Percent tumor nuclei: 10; Percent necrosis: 0.
- Sample C3L-02890-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -15 days; Method of sample procurement: Blood Draw.
